Somatic mutation profile of tumor specimen BA2937D (aliquot aq-BA2937D) from BEATAML1.0 case 2212, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,298 days).
Specimen BA2937D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07f442bf-58d0-44df-98e6-827945982ae7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2009D (Solid Tissue Normal), aliquot aq-BA2009D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15ab3807-faeb-4bc5-bb2c-3797dba1f2c6

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IPO5 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- IQGAP3 | c.3924G>T p.L1308= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
